Somatic mutation profile of tumor specimen MP2PRT-PATGSJ-TMP1-A (aliquot MP2PRT-PATGSJ-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATGSJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,735 days).
Specimen MP2PRT-PATGSJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d80f6a6d-ecc7-4b93-b3cc-adfd2e63f1c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGSJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGSJ-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/887db566-5468-4cda-b089-09af526005fe

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, In Frame Ins 1, Frame Shift Del 1, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NDUFAF6 | c.559_563del p.Y187Nfs*65 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs765915512; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- DENND2B | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 183/469 reads (39%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs560823063, COSV58201459; called by muse, mutect2, varscan2
- RIT1 | c.242_243insAGG p.E81_F82insG | In Frame Ins (INS) | VAF 82/254 reads (32%) | called by mutect2, pindel, varscan2
- CGN | c.1557G>A p.R519= | Silent (SNP) | VAF 176/442 reads (40%) | called by muse, mutect2, varscan2
- KCNJ5 | c.183C>T p.N61= | Silent (SNP) | VAF 157/465 reads (34%) | catalogued as rs760931417, COSV100610616; called by muse, mutect2, varscan2
- NXF3 | c.864C>A p.T288= | Silent (SNP) | VAF 186/470 reads (40%) | called by muse, mutect2, varscan2
- RASGRF1 | c.2526A>G p.S842= | Silent (SNP) | VAF 85/229 reads (37%) | called by muse, mutect2, varscan2
- GOLGA2 | c.-32G>A | 5'UTR (SNP) | VAF 128/379 reads (34%) | catalogued as rs751911459, COSV60791808; called by muse, mutect2, varscan2
